Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7410, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7410-01A (Primary Tumor).

[page 1 of 2]
SUPPLEMENTAL REPORT

DIAGNOSIS :

(A) TOTAL LARYNGECTOMY, RIGHT MODIFIED RADICAL NECK DISSECTION:
MODERATELY DIFFERENTIATED INVASIVE SQUAMOUS CARCINOMA
OF GLOTTIS, INVOLVING THE RIGHT TRUE VOCAL CORD (1.4 X
1.1 X 0.8 CM).

Surgical margins of resection free of tumor.

RIGHT MODIFIED RADICAL NECK DISSECTION: ONE OUT OF TEN
LYMPH NODES WITH METASTATIC SQUAMOUS CARCINOMA WITH
EXTRACAPSULAR EXTENSION.

Zone 3 (subdigastric): Four lymph nodes, no tumor present.

Zone 4 (midjugular): One lymph node, no tumor present.

Zone 5 (lower jugular): No lymph node identified.

ZONE 6 (UPPER POSTERIOR CERVICAL): One lymph node with
METASTATIC SQUAMOUS CARCINOMA SHOWING EXTRACAPSULAR
EXTENSION. (SEE COMMENT)

JUGULAR VEIN WITH TUMOR EXTENDING INTO THE ADVENTITIA WITHOUT
LUMINAL INVOLVEMENT.

Zone 7 (midposterior cervical): Two lymph nodes, no tumor present.

Zone 8 (lower posterior cervical): Two lymph nodes, no tumor
present. (See comment)

COMMENT: The lymph node from upper posterior cervical compartment measures
2.6 x 2.0 x 2.0 cm and shows metastatic squamous carcinoma with extension
into the soft tissues. However, the number of lymph nodes involved by
squamous carcinoma is uncertain due to the extracapsular extension and only
focal thin rim of lymphoid tissue at one pole only. Multiple cross sections
from the thyroid cartilage fail to show involvement by metastatic invasive
squamous carcinoma.

(B) LEFT PHARYNGEAL MARGIN, BIOPSY:

Squamous mucosa, scattered muscle, no tumor present.

(C) RIGHT PHARYNGEAL MARGIN, BIOPSY:

Squamous mucosa, no tumor present.

(D) TONGUE, MARGIN, BIOPSY:

Squamous mucosa, no tumor present.

DIAGNOSIS

[page 2 of 2]
Case type: Surgical History

- (A) TOTAL LARYNGECTOMY, RIGHT MODIFIED RADICAL NECK DISSECTION:
MODERATELY DIFFERENTIATED INVASIVE SQUAMOUS CARCINOMA
OF GLOTTIS, INVOLVING THE RIGHT TRUE VOCAL CORD (1.4 X
1.1 X 0.8 CM).
Surgical margins of resection free of tumor.
RIGHT MODIFIED RADICAL NECK DISSECTION: ONE OUT OF TEN
LYMPH NODES WITH METASTATIC SQUAMOUS CARCINOMA WITH
EXTRACAPSULAR EXTENSION.
Zone 3 (subdigastric): Four lymph nodes, no tumor present.
Zone 4 (midjugular): One lymph node, no tumor present.
Zone 5 (lower jugular): No lymph node identified.
ZONE 6 (UPPER POSTERIOR CERVICAL): One lymph node with
METASTATIC SQUAMOUS CARCINOMA SHOWING EXTRACAPSULAR
EXTENSION. (SEE COMMENT)
JUGULAR VEIN WITH TUMOR EXTENDING INTO THE ADVENTITIA WITHOUT
LUMINAL INVOLVEMENT.
Zone 7 (midposterior cervical): Two lymph nodes, no tumor present.
Zone 8 (lower posterior cervical): Two lymph nodes, no tumor
present. (See comment)
- COMMENT: The lymph node from upper posterior cervical compartment measures
2.6 x 2.0 x 2.0 cm and shows metastatic squamous carcinoma with extension
into the soft tissues. However, the number of lymph nodes involved by
squamous carcinoma is uncertain due to the extracapsular extension and only
focal thin rim of lymphoid tissue at one pole only.
- (B) LEFT PHARYNGEAL MARGIN, BIOPSY:
Squamous mucosa, scattered muscle, no tumor present.
- (C) RIGHT PHARYNGEAL MARGIN, BIOPSY:
Squamous mucosa, no tumor present.
- (D) TONGUE, MARGIN, BIOPSY:
Squamous mucosa, no tumor present.

SPECIMEN

- (A) TOTAL LARYNGECTOMY, RIGHT MODIFIED RADICAL NECK DISSECTION:

SNOMED CODES

T-24400,M-80703

Source: NCI Genomic Data Commons file 20cdf6ad-db3a-452f-be9b-929730e2a1c7 (TCGA-CV-7410.4DDEED3D-B678-4500-BBDA-9D8429A3A9FD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).